Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LH-01A (Primary Tumor).

[page 1 of 3]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes & ovaries
- 2: SP: Lt. external iliac lateral group
- 3: SP: Lt. external iliac medial group
- 4: SP: Lt. obturator nodes (
- 5: SP: Lt. hypogastric nodes (
- 6: SP: Rt. external iliac lateral group
- 7: SP: Rt. external iliac medial group (
- 8: SP: Rt. obturator nodes
- 9: SP: Rt. hypogastric nodes (
- 10: SP: Rt. para-aortic nodes
- 11: SP: Lt. para-aortic nodes

100-0-3
mixed
adenocarcinoma, endometrioid and serous, NOS 8441/3
(code to highest)
Site: endometrium C54.1 lw 5/11

DIAGNOSIS:

- 1) UTERUS, FALLOPIAN TUBES AND OVARIES; TOTAL ABDOMINAL
HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY:
- ENDOMETRIAL ADENOCARCINOMA, MIXED SEROUS AND ENDOMETRIOID TYPES, WITH
A PREDOMINANCE OF THE SEROUS COMPONENT, ARISING IN AND CONFINED TO AN
ENDOMETRIAL POLYP, 2.0 X 1.0 CM (SEE NOTE).
- VASCULAR INVASION IDENTIFIED IN POLYP ONLY.
- LEIOMYOMATA.
- BENIGN CERVIX, FALLOPIAN TUBES AND OVARIES.

NOTE: DR. [REDACTED] HAS REVIEWED THIS PORTION OF THE CASE AND CONCURS.

- 2) LYMPH NODES, LEFT EXTERNAL ILIAC, LATERAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC, MEDIAL; EXCISION:
- NO LYMPH NODES IDENTIFIED.
- 4) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

PATH
REPORT

** Continued on next page **

lw 5/1/11

[page 2 of 3]
TSS Name,

Page 2 of 6

- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC, LATERAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC, MEDIAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 9) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).
- 11) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 3]
ISS Name/##:

----- Page 2 of 6

- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC, LATERAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC, MEDIAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 9) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).
- 11) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file f9257655-de5c-4cb9-9a24-e862ab3d1f68 (TCGA-AP-A0LH.78E73020-1173-45DA-BDBA-DFB1CF7BCB41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).